TCGA case TCGA-D8-A1JN — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Greater Poland Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/28911b97-42bf-4189-9961-522fc0aeebc6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Poland; Age at index: 80 years; Vital status: Alive.

Diagnoses (1)
1. Lobular carcinoma, NOS: ICD-O-3 morphology code: 8520/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 80.3 years (29,331 days); Year of diagnosis: 2010; Method of diagnosis: Incisional Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N3a; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 11; Lymph nodes tested: 13.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole; Treatment intent type: Adjuvant; Days to treatment start: 63 days; Treatment outcome: Treatment Ongoing; Prescribed dose: 1; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 217 days; Disease response: Tumor Free.
- Days to follow up: 620 days (1.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Equivocal.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Positive.
- PGR (IHC): Positive; Test value range: <10%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D8-A1JN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 180 mg.
  Slide TCGA-D8-A1JN-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-D8-A1JN-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D8-A1JN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Er positivity method: manual counting; Pr positivity define method: manual counting; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Infiltrating Lobular Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Er positivity scale other: >75%; Her2 positivity method text: DAKOHercepTest TM; Her2 and cent17 scale other: HER2 amplification - negative; Her2 fish method: PathVision HER2 DNA Probe Kit; Prospective collection: Yes; Retrospective collection: No; Pr status IHC percent positive: <10%.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left.
- Follow-up form: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment: Pharmaceutical therapy drug name: anastrozolum.
- Drug treatment, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 620 days; disease-specific survival: no event (censored), 620 days; disease-free interval: no event (censored), 620 days; progression-free interval: no event (censored), 620 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D8-A1JN-01A-11D-A13J-01): tumor purity 0.94, ploidy 1.94, whole-genome doublings 0.
